Gene-level copy-number profile of tumor specimen C3N-01643-04 from CPTAC case C3N-01643, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.2 years (24,920 days).
Specimen C3N-01643-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 081a5195-c37d-4c66-92ff-941a36447ed7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01643-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/02725534-9dbd-4528-aa19-1ee1eee1d62d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,856; copy number 2: 56,042; copy number 3: 15.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
